TARGET case TARGET-40-PAMRHD — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f065171-8c64-5af3-897a-424144f69389

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 10 years; Vital status: Dead; Days to death: 74 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 10.8 years (3,942 days); Year of diagnosis: 2003; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 74 days; Sites of involvement: Lung, NOS / Bone, NOS.
   Treatment given: Protocol identifier: AOST0121.

Follow-up (2 entries)
- Days to follow up: 39 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 39 days; Days to first event: 39 days; First event: Relapse.
- Days to follow up: 74 days; Year of follow up: 2003.

Biospecimens (2 samples)
- Sample TARGET-40-PAMRHD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PAMRHD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 74
- Disease at diagnosis: Metastatic
- Metastasis site: Bone and lung
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Site of initial relapse: Lung

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PAMRHD-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 97
- % Non Tumor Nuclei: Top from Biopsy: 3
- % Cellular Tumor: Top from Biopsy: 86
- % Normal: Top from Biopsy: 2
- % Stroma: Top from Biopsy: 2
- % Necrosis: Top from Biopsy: 10
- % Tumor Nuclei: Bottom from Biopsy: 97
- % Non Tumor Nuclei: Bottom from Biopsy: 3
- % Cellular Tumor: Bottom from Biopsy: 90
- % Normal: Bottom from Biopsy: 2
- % Stroma: Bottom from Biopsy: 2
- % Necrosis: Bottom from Biopsy: 6
- PASS/FAIL: pass
